TCGA case TCGA-4G-AAZG — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Sapienza University of Rome. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c60eb7be-c85c-4338-a20b-51948d43bf2a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Italy; Age at index: 75 years; Vital status: Alive.

Diagnoses (2)
1. Cholangiocarcinoma (the primary disease): ICD-O-3 morphology code: 8160/3; ICD-10 code: C22.1; Tissue or organ of origin: Intrahepatic bile duct; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 75.3 years (27,490 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,716 days (4.7 years); Ishak fibrosis score: 1,2 - Portal Fibrosis.
   Pathology details: Consistent pathology review: Yes; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Sigmoid colon; Classification of tumor: Prior primary; Age at diagnosis: 58.6 years (21,389 days); Days to diagnosis: -6,101 days (-16.7 years); AJCC staging edition: 4th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 0 days; Treatment anatomic sites: Colon.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,716 days (4.7 years); Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- CA19-9: 166.7 U/mL; Blood test normal range lower: 0; Blood test normal range upper: 35.
- Creatinine 1.1 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.3].
- Albumin 3.6 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 4.5].
- Platelets 189000 (unit not recorded by GDC) [Blood test normal range lower: 15000; Blood test normal range upper: 450000].
- Total Bilirubin 1.3 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1.2].
- Alpha Fetoprotein 2 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 9].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.1 [Blood test normal range lower: 0.8; Blood test normal range upper: 1.2].

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-4G-AAZG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 110 mg.
  Slide TCGA-4G-AAZG-01A-01-TS1: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 80; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-4G-AAZG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, intrahepatic; Definitive surgical procedure: Lobectomy.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: Colon Adenocarcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: left colectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,716 days; disease-specific survival: no event (censored), 1,716 days; disease-free interval: no event (censored), 1,716 days; progression-free interval: no event (censored), 1,716 days.
